Surgical pathology report (de-identified scan), TCGA case TCGA-55-A4DF, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-55-A4DF-01A (Primary Tumor).

[page 1 of 4]
SURGICAL PATHOLOGY:

PROCEDURE DATE: RECEIVED DATE: REPORT DATE:

COPY TO: [REDACTED]

1CD-03

adenocarcinoma, NOS

8140/3

Site: lung, lower lobe

C34.3

IO Consultation

FS DIAGNOSIS:

#1: "No neoplasm consistent with organizing pneumonia" reported to Dr. [REDACTED] positive patient ID, by Dr. [REDACTED]

9-12-12

RD

Campus.

#2: "Adenocarcinoma" reported to Dr. [REDACTED] positive patient ID, by Dr. [REDACTED]

Pre-Op Diagnosis

Right lower and upper lobe mass

Post-Op Diagnosis

Same as above

Clinical History

Nothing indicated

Gross Description:

Five parts

Container labeled "[REDACTED] 1 - right lower lobe wedge #1" is a previously sectioned wedge shaped portion of recognizable pulmonary parenchyma with a closed staple line as the margin of resection. The specimen as received weighs 4.3 grams and on reconstruction measures approximately 4.5 x 1.6 x 1.4 cm. The pleura is wrinkled gray red. The cut surface is rubbery to spongy and pink red without discrete gross mass lesion. The portion submitted for frozen section is reported as "no neoplasm consistent with organizing pneumonia" reported to [REDACTED] positive patient ID, by [REDACTED]. The frozen residue is submitted labeled A. The remaining tissue is sectioned and submitted labeled B-D.

Container labeled "[REDACTED] 2 - right lower lobe wedge #2" is a previously sectioned partially fragmented wedge shaped portion of recognizable pulmonary parenchyma weighing as received 22 grams and on reconstruction measures approximately 5.7 x 4.2 x 3.0 cm. the closed staple line is the margin of resection. The pleura is

Reviewed (Initials):	[Signature]	

[page 2 of 4]
wrinkled gray pink with an eccentric 2.5 x 2.5 cm plaque like area of tan gray discoloration and umbilication noted 0.8 cm from the nearest staple line margin. This is sectioned to reveal a well defined lobulated gritty gray tan fibrotic lesion with focally anthracotic gritty gray tan fibrotic cut surface measuring 2.7 x 2.5 x 2.0 cm. This grossly extends to but not through the pleura. The remaining parenchyma is spongy and pink red. The portion submitted for frozen section is reported as "adenocarcinoma" reported to Dr.

ositive patient ID, by Dr. [REDACTED]. In addition, there are three tissue cassettes within the specimen container labeled

The frozen residue is submitted labeled A. The remaining lesion and surrounding tissue is submitted labeled B-H. Representative remaining parenchyma is submitted labeled I-J.

Container labeled "[REDACTED] 3 - right upper lobe wedge" has a 15 gram wedge shaped portion of recognizable pulmonary parenchyma with a closed staple line as the margin of resection. The specimen is 6.0 x 3.0 x 2.1 cm. The pleura is slightly wrinkled pink red with marked anthracotic streaking and a few areas of apparent plaque like thickening up to 0.8 cm which are poorly defined. On sectioning in the central portion of the specimen there is an intraparenchymal 1.0 x 0.9 x 0.7 cm lobulated gray tan fibrotic nodular lesion noted 0.4 cm from the nearest staple line margin. This has a gritty gray tan fibrotic cut surface. The remaining parenchyma is spongy congested and markedly anthracotic streaked with moderate honeycombing. The specimen is step sectioned and entirely submitted in 10 cassettes.

Container labeled "[REDACTED] 4 - level 4 lymph node" are 1.6 x 1.0 x 0.3 cm of gray brown to black fleshy tissue fragments which are entirely submitted in a single cassette.

Container labeled "[REDACTED] 5 - level 7 lymph node" are 4.0 x 2.2 x 1.1 cm partially fragmented lobulated portion of fleshy gray black tissue with a slightly mottled fleshy gray black cut surface. This is received along with 1.2 x 0.9 x 0.4 cm of similar irregular tissue fragments. The largest portion is sectioned and submitted labeled A-E while the smaller portion is entirely submitted labeled F.

Microscopic Description:

Sections of specimen #2 show a large cell malignant neoplasm that in areas shows prominent gland formation. These glandular area blend into more solid nests of neoplastic cells. These are supported by a dense fibrous stroma and alternate with areas of necrosis. The neoplasm extends into the pleural but not onto the pleural surface.

Sections of the neoplasm within the right upper lobe specimen #3 show a large cell malignant neoplasm with a distinctly different growth pattern. In this neoplasm the cells form sheets that have irregular borders. The cells have a moderate amount of eosinophilic cytoplasm and enlarged pleomorphic nuclei.

Sections of the lymph node specimens show no areas of metastatic carcinoma.

Immunohistochemical stains are performed on the neoplasm in the right lower lobe specimen and right upper lobe specimen. The right

[page 3 of 4]
lower lobe specimen shows the neoplasm to be positive for CK7 and negative for CK20. Some of the cells are strongly positive for TTF1. These are in the more glandular areas. The more solid areas are negative for this marker. The more solid areas do express positivity for CDX-2 where the glandular areas tend to be negative for this marker. The cells are negative for p63. This staining pattern would support this being an adenocarcinoma of pulmonary origin. It is unclear why some of the cells mark with the colorectal marker CDX-2. This same panel performed on the right upper lobe specimen show the neoplastic cells to be negative for both CK7 and CK20. The cells are negative for CDX-2 and TTF1. The cells are strongly positive for p63. This staining pattern would support this being a squamous carcinoma that is very poorly differentiated. The immunohistochemical control slides stain appropriately.

Final Diagnosis

Right lung lower lobe wedge biopsy #1 with frozen section:

Negative for carcinoma.

Alveolar changes focally with pneumocyte hyperplasia consistent with organizing pneumonia and atelectasis.

Frozen section diagnosis is confirmed.

Lung, right lower lobe wedge biopsy #2 with frozen section:

Tumor characteristics:

Histologic type: Adenocarcinoma.

Histologic grade: Poorly differentiated.

Tumor size: 2.7 x 2.5 x 2.0 cm.

Tumor focality: Single focus of right lower lobe.

Visceral pleural invasion: Yes (PL1).

Lymphovascular space invasion: Not identified.

Tumor extension: Not identified.

Treatment effect: Not identified.

Surgical margin status:

Tumor distance from bronchial margin: Not applicable.

Tumor distance from stapled margin: 0.8 cm.

Lymph node status:

See specimens four and five.

Lung, right upper lobe, wedge biopsy:

Histologic type: Poorly differentiated squamous carcinoma (see above comments).

Histologic grade: Poorly differentiated.

Tumor site: Right upper lobe.

Tumor focality: Right upper lobe, single focus

Tumor size: 1.0 x 0.9 x 0.7 cm.

Visceral pleural invasion: Not identified.

Lymphovascular space invasion: No.

Tumor extension: No.

Treatment effect: Not identified.

Surgical margin status:

Tumor distance from bronchial margin: Not applicable.

Tumor distance from parenchymal stapled margin: 0.4 cm.

Tumor distance from pleural surface: 0.8 cm (as measured on histologic sections).

Lymph node status:

See specimens four and five.

Lymph node level 4, excisional biopsy:

Negative for tumor (0/1).

Lymph node level 7, excisional biopsy:

Negative for tumor (0/1).

Pathology stage:

[page 4 of 4]
Comments

The tumor morphology present in specimen three shows focal areas with morphology compatible with a poorly differentiated adenocarcinoma. The possibility of focal squamous differentiation cannot be completely excluded.

This report has been finalized at the [REDACTED]

<Sign Out Dr. Signature>

Source: NCI Genomic Data Commons file fc64aa15-55a1-419e-89cc-928d901f0c8d (TCGA-55-A4DF.25E84F93-E9AF-4A09-B3A9-86C5AC80BD4A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).